Somatic mutation profile of tumor specimen TCGA-22-5485-01A (aliquot TCGA-22-5485-01A-01D-1632-08) from TCGA case TCGA-22-5485, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 58.8 years (21,488 days).
Specimen TCGA-22-5485-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) acb175d9-feab-4cbf-be47-ad423e1c34b5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-22-5485-11A (Solid Tissue Normal), aliquot TCGA-22-5485-11A-01D-1632-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8f2f84da-6627-45b5-8c33-06f11f07f695

The open-access MAF lists 242 somatic variants for this specimen: 183 protein-altering or splice-affecting, 52 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 154, Silent 52, Frame Shift Del 9, Nonsense Mutation 7, Splice Region 4, Intron 4, Splice Site 3, Frame Shift Ins 3, 3'Flank 2, In Frame Del 2, 3'UTR 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLMP | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 67/250 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs587776965, CS121568, COSV71650019; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.484_486dup p.I162dup | In Frame Ins (INS) | VAF 23/38 reads (61%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ABCC9 | c.858G>T p.W286C | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV53976669; called by muse, mutect2, varscan2
- ACTN4 | c.997G>T p.E333* | Nonsense Mutation (SNP) | VAF 11/27 reads (41%) | catalogued as COSV53147591; called by muse, mutect2
- ACTR1A | c.698C>A p.T233K | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT tolerated (0.74); PolyPhen benign (0.169); catalogued as COSV100883731, COSV64023594; called by muse, mutect2, varscan2
- ADGRB3 | c.3494G>T p.C1165F | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.24); catalogued as COSV53250594; called by muse, mutect2, varscan2
- ADGRG3 | c.526G>T p.V176L | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV59650277, COSV59651601; called by muse, mutect2, varscan2
- AKAP6 | c.1254G>T p.K418N | Missense Mutation (SNP) | VAF 70/185 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.218); catalogued as COSV55219581, COSV55234882; called by muse, mutect2, varscan2
- ANK3 | c.4525G>T p.A1509S | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.005); catalogued as COSV55065462; called by muse, mutect2, varscan2
- APOH | c.941A>T p.Q314L | Missense Mutation (SNP) | VAF 61/90 reads (68%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as COSV52773388; called by muse, mutect2, varscan2
- AQP12A | c.331C>A p.Q111K | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV61837288; called by muse, mutect2, varscan2
- ARHGAP36 | c.832G>T p.D278Y | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52265611, COSV52268617; called by muse, mutect2, varscan2
- ARHGEF12 | c.1555G>A p.A519T | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63105825; called by muse, mutect2, varscan2
- ARL14EP | c.683C>A p.S228Y | Missense Mutation (SNP) | VAF 47/158 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56342092, COSV56343111; called by muse, mutect2, varscan2
- ATF6B | c.1829A>G p.N610S | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64352104; called by muse, mutect2, varscan2
- ATP8B3 | c.1300C>G p.L434V | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0.063); catalogued as COSV59544583; called by muse, mutect2, varscan2
- BACH2 | c.1682A>G p.H561R | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.321); catalogued as rs1466499840, COSV57598217; called by muse, mutect2, varscan2
- BCAM | c.1249G>T p.D417Y | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs747031001, COSV54303170, COSV54303356; called by muse, mutect2
- BFSP1 | c.731C>A p.A244E | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.495); catalogued as COSV64900791; called by muse, mutect2, varscan2
- C20orf141 | c.286C>A p.R96S | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV63028326; called by muse, mutect2, varscan2
- CABYR | c.1005A>T p.E335D | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.018); catalogued as COSV59111515; called by muse, mutect2, varscan2
- CCDC7 | c.1264G>A p.G422R | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV53231459; called by muse, mutect2, varscan2
- CCKBR | c.139G>T p.A47S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as COSV58102743; called by muse, mutect2, varscan2
- CCL26 | c.158C>G p.T53S | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.946); catalogued as COSV50013723; called by muse, mutect2, varscan2
- CCNB2 | c.613C>T p.R205W | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369137460; called by muse, mutect2, varscan2
- CD209 | c.472G>C p.G158R | Missense Mutation (SNP) | VAF 107/237 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.779); catalogued as COSV52655375; called by muse, varscan2
- CD37 | c.286C>T p.L96F | Missense Mutation (SNP) | VAF 63/110 reads (57%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV60544730; called by muse, mutect2, varscan2
- CDC42EP1 | c.847C>A p.H283N | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV50757116; called by muse, mutect2
- CDK20 | c.843+1G>T p.X281_splice (on ENST00000325303 / NM_001039803.3; = p.X260_splice on NM_012119.4) | Splice Site (SNP) | VAF 51/76 reads (67%) | catalogued as COSV57483177, COSV57484011; called by muse, mutect2, varscan2
- CELSR1 | c.1031A>C p.K344T | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.017); catalogued as COSV53093400; called by muse, mutect2, varscan2
- CEP63 | c.437T>C p.I146T | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as rs145156085; called by muse, mutect2, varscan2
- CLSTN3 | c.1772A>G p.Q591R | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.062); catalogued as COSV56937873; called by muse, mutect2, varscan2
- COLEC12 | c.1435G>A p.G479S | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68371739; called by muse, mutect2, varscan2
- COPS2 | c.945A>T p.V315= | Splice Region (SNP) | VAF 8/28 reads (29%) | catalogued as COSV54645952; called by muse, mutect2
- CPN2 | c.1528C>T p.Q510* | Nonsense Mutation (SNP) | VAF 14/55 reads (25%) | catalogued as COSV60470968; called by mutect2, varscan2
- CR1L | c.1046C>A p.S349Y | Missense Mutation (SNP) | VAF 50/273 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.271); catalogued as COSV54327968; called by muse, mutect2, varscan2
- CRB1 | c.3503G>A p.G1168E | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66331362; called by muse, mutect2, varscan2
- CTNNA3 | c.2531C>A p.P844Q | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65525966; called by muse, mutect2, varscan2
- CTNND2 | c.1604T>C p.I535T | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as rs1424310228, COSV58901907; called by muse, mutect2, varscan2
- CYLC1 | c.595G>C p.D199H | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100253896, COSV61412186; called by muse, mutect2, varscan2
- DNAH8 | c.1877C>T p.A626V | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.498); catalogued as COSV59458889; called by muse, mutect2, varscan2
- DSCAML1 | c.5618G>T p.R1873L (on ENST00000321322; = p.R1813L on NM_020693.4) | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58395328; called by muse, mutect2, varscan2
- ECT2 | c.2612A>C p.D871A (on ENST00000392692 / NM_001349098.2; = p.D840A on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT tolerated (0.75); PolyPhen benign (0.005); catalogued as rs756920683, COSV51690580; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.391G>T p.G131C | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV56182091; called by muse, mutect2, varscan2
- EEPD1 | c.311G>T p.G104V | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.024); catalogued as COSV54200086; called by muse, mutect2, varscan2
- EFCAB6 | c.4321C>A p.R1441S | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53061785, COSV53066189; called by muse, mutect2, varscan2
- EIF4G3 | c.4379C>G p.P1460R | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.093); catalogued as COSV51686480; called by muse, mutect2, varscan2
- EPHB2 | c.949C>A p.L317M | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.243); catalogued as COSV65863585; called by muse, mutect2, varscan2
- FAM120B | c.488T>A p.V163E | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53005647; called by muse, varscan2
- FBXL19 | c.784A>T p.R262W | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as COSV57943464; called by muse, mutect2, varscan2
- FGB | c.387G>C p.E129D | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV57418778; called by muse, mutect2, varscan2
- FMN2 | c.4767C>A p.A1589= | Splice Region (SNP) | VAF 13/31 reads (42%) | catalogued as COSV60437351; called by muse, mutect2, varscan2
- FSCB | c.874C>A p.Q292K | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.047); catalogued as COSV61218660; called by muse, mutect2, varscan2
- FSHR | c.1651C>T p.H551Y | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.786); catalogued as COSV58627091; called by muse, mutect2, varscan2
- FTO | c.953G>T p.S318I | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV67112619; called by muse, mutect2, varscan2
- GABRR2 | c.896C>A p.T299K | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV68765388; called by muse, mutect2, varscan2
- GAL3ST3 | c.754C>T p.R252W | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs766591146, COSV100360960, COSV61748650; called by muse, mutect2, varscan2
- GIN1 | c.908A>G p.H303R | Missense Mutation (SNP) | VAF 53/85 reads (62%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV67537115; called by muse, mutect2, varscan2
- GRID1 | c.2957C>A p.P986H | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); catalogued as COSV60036997; called by muse, mutect2, varscan2
- GRM8 | c.1696C>A p.R566S | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.241); catalogued as COSV58840197; called by muse, mutect2, varscan2
- GUCY1A2 | c.1388A>T p.D463V | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56491597; called by muse, mutect2, varscan2
- H6PD | c.1036A>G p.N346D | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV66231356; called by muse, mutect2, varscan2
- HAVCR2 | c.223G>T p.V75L | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV57153511; called by muse, mutect2, varscan2
- HCN3 | c.484C>T p.R162W | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs34277242, COSV64234479; called by muse, mutect2, varscan2
- HELZ2 | c.896G>T p.R299L | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV64409258, COSV64409957; called by muse, mutect2, varscan2
- HMCN1 | c.10693G>T p.D3565Y | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54913223; called by muse, mutect2, varscan2
- HMCN1 | c.10694A>T p.D3565V | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54913239; called by muse, mutect2, varscan2
- IFT43 | c.445-1G>A p.X149_splice (on ENST00000314067 / NM_001102564.3; = p.X154_splice on NM_052873.3) | Splice Site (SNP) | VAF 12/29 reads (41%) | catalogued as COSV53139471; called by muse, mutect2, varscan2
- ITFG2 | c.262G>T p.G88C | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57390080; called by muse, mutect2, varscan2
- KCNH1 | c.2027C>T p.A676V (on ENST00000271751 / NM_172362.3; = p.A649V on NM_002238.4) | Missense Mutation (SNP) | VAF 3/51 reads (6%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.9); catalogued as COSV55088778; called by muse, mutect2
- KCNT2 | c.173C>G p.S58* | Nonsense Mutation (SNP) | VAF 5/11 reads (45%) | catalogued as COSV54088767; called by muse, mutect2, varscan2
- KHDRBS2 | c.901G>T p.E301* | Nonsense Mutation (SNP) | VAF 8/30 reads (27%) | catalogued as COSV55467338; called by muse, mutect2, varscan2
- KLHL20 | c.172A>T p.I58F | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV52943142; called by muse, mutect2, varscan2
- KLHL31 | c.760C>A p.L254I | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.832); catalogued as rs1057115622, COSV63882030; called by muse, mutect2, varscan2
- LAS1L | c.656T>G p.V219G | Missense Mutation (SNP) | VAF 56/198 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV56707870; called by muse, mutect2, varscan2
- LRFN5 | c.1384A>G p.R462G | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV53263526; called by muse, mutect2, varscan2
- LRP1B | c.9559A>G p.R3187G | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67241458; called by muse, mutect2, varscan2
- LSM14A | c.523A>G p.T175A | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0.079); catalogued as rs1181426658, COSV70885331; called by muse, mutect2, varscan2
- MAB21L1 | c.833T>C p.V278A | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as COSV59797447; called by muse, mutect2, varscan2
- MAP7D3 | c.2011G>T p.E671* | Nonsense Mutation (SNP) | VAF 30/90 reads (33%) | catalogued as COSV60171522; called by muse, mutect2, varscan2
- MDN1 | c.2333A>T p.K778M | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV65524142; called by muse, mutect2, varscan2
- MED12 | c.3125G>T p.S1042I | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV61344911; called by muse, mutect2, varscan2
- MED26 | c.997C>T p.P333S | Missense Mutation (SNP) | VAF 17/19 reads (89%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV54661365; called by muse, mutect2, varscan2
- MORC4 | c.1163C>A p.T388K | Missense Mutation (SNP) | VAF 56/170 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV55243870; called by muse, varscan2
- MTNR1A | c.790G>T p.D264Y | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as COSV56156728; called by muse, mutect2, varscan2
- MUC5B | c.2098C>G p.R700G | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV71593629; called by muse, mutect2, varscan2
- MVP | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs758642200, COSV62422517; called by muse, mutect2, varscan2
- MYF5 | c.101C>A p.P34Q | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.424); catalogued as COSV57354370, COSV99953253; called by muse, mutect2, varscan2
- MYH1 | c.1359G>T p.K453N | Missense Mutation (SNP) | VAF 141/188 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as COSV56851511; called by muse, mutect2, varscan2
- MYH6 | c.3193C>G p.Q1065E | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV62452044; called by muse, mutect2, varscan2
- MYO7A | c.3091G>A p.D1031N | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.994); catalogued as rs782467644, COSV68685351; called by muse, mutect2, varscan2
- NAV1 | c.1198A>T p.M400L | Missense Mutation (SNP) | VAF 52/95 reads (55%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55220480; called by muse, mutect2, varscan2
- NAV3 | c.893G>T p.G298V | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.499); catalogued as COSV57090895, COSV57097156; called by muse, mutect2, varscan2
- NEIL3 | c.1443C>G p.N481K | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV52811633; called by muse, mutect2, varscan2
- NFATC2 | c.2034C>T p.V678= | Splice Region (SNP) | VAF 8/56 reads (14%) | catalogued as COSV65357774; called by muse, mutect2
- NLGN4X | c.1783C>T p.P595S | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV52024681, COSV99321784; called by muse, mutect2, varscan2
- NLRP5 | c.1273C>A p.R425S | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.9); catalogued as COSV66761960, COSV66762753; called by muse, mutect2
- NOTCH1 | c.1648T>A p.Y550N | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53064627; called by muse, mutect2, varscan2
- OR10G8 | c.700C>A p.H234N | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV70908768; called by muse, mutect2, varscan2
- OR2M2 | c.524C>A p.A175D | Missense Mutation (SNP) | VAF 163/338 reads (48%) | SIFT tolerated (0.97); PolyPhen benign (0.02); catalogued as COSV62898689; called by muse, mutect2, varscan2
- OR56A4 | c.1033A>G p.I345V | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.044); catalogued as COSV58111005; called by muse, mutect2, varscan2
- OR5T3 | c.155T>A p.I52K | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.317); catalogued as COSV57381438; called by muse, mutect2, varscan2
- OR5T3 | c.874A>G p.I292V | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0.173); catalogued as rs774140010, COSV57381448; called by muse, mutect2, varscan2
- OR7A10 | c.912del p.F305Sfs*20 | Frame Shift Del (DEL) | VAF 28/51 reads (55%) | catalogued as COSV50166188; called by mutect2, pindel, varscan2
- OTC | c.178T>A p.S60T | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.295); catalogued as COSV50002731; called by muse, mutect2, varscan2
- OTC | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.014); catalogued as CM062948, COSV50002744; called by muse, mutect2, varscan2
- PCDH10 | c.2548C>T p.H850Y | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious (0.04); PolyPhen benign (0.142); catalogued as rs757663766, COSV52097545; called by muse, mutect2, varscan2
- PCDHB6 | c.1012G>T p.V338L | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.251); catalogued as COSV50701853; called by muse, mutect2, varscan2
- PDE3B | c.2908G>A p.G970S | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56386114; called by muse, mutect2, varscan2
- PDGFRB | c.2156C>T p.A719V | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0.257); catalogued as COSV55806854; called by muse, mutect2, varscan2
- PDS5B | c.550A>G p.I184V | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.768); catalogued as COSV59729587; called by muse, mutect2, varscan2
- PELP1 | c.3010G>T p.G1004W | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); catalogued as COSV52589306; called by muse, mutect2, varscan2
- PEX5L | c.20A>T p.Q7L | Missense Mutation (SNP) | VAF 49/240 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); catalogued as COSV55849304; called by muse, mutect2, varscan2
- PGAP1 | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61327308; called by muse, mutect2, varscan2
- PI16 | c.70C>A p.P24T | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.19); catalogued as COSV65448360; called by muse, mutect2, varscan2
- PLPPR5 | c.298C>A p.Q100K | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV54174952, COSV99586878; called by muse, mutect2, varscan2
- PNLIPRP3 | c.1132G>T p.G378C | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs1377796371; called by muse, mutect2, varscan2
- PROSER3 | c.1249C>T p.P417S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV56553981; called by muse, mutect2
- PRR5L | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV61122225; called by muse, mutect2, varscan2
- PTPN3 | c.614C>A p.S205Y | Missense Mutation (SNP) | VAF 36/51 reads (71%) | SIFT tolerated (0.48); PolyPhen benign (0.262); catalogued as COSV52707622; called by muse, mutect2, varscan2
- PTPRN | c.775C>T p.H259Y | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.139); catalogued as COSV55349494; called by mutect2, varscan2
- PYDC1 | c.58C>T p.L20F | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.036); catalogued as COSV57251665; called by muse, mutect2, varscan2
- RADX | c.658T>A p.S220T | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.077); catalogued as COSV65319153; called by muse, mutect2, varscan2
- RBMX | c.413T>C p.F138S | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.332); catalogued as COSV57809975; called by muse, mutect2, varscan2
- RC3H1 | c.3292A>T p.S1098C | Missense Mutation (SNP) | VAF 56/105 reads (53%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV51204633; called by muse, mutect2, varscan2
- RFX6 | c.1160C>A p.T387K | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100263545, COSV60586568; called by muse, mutect2, varscan2
- RHOU | c.289G>A p.V97M | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as rs962507772, COSV64208756; called by muse, mutect2, varscan2
- RPTN | c.527A>T p.Q176L | Missense Mutation (SNP) | VAF 219/441 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV60167837; called by muse, mutect2, varscan2
- RSPO1 | c.201C>A p.N67K | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.506); catalogued as rs767375391, COSV62974619; called by muse, mutect2, varscan2
- RTL9 | c.3070T>A p.S1024T | Missense Mutation (SNP) | VAF 74/215 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV71825831; called by muse, mutect2, varscan2
- RYR2 | c.5652G>T p.K1884N | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs202117250, COSV63684566, COSV63694243; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR3 | c.4063T>A p.Y1355N | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.414); catalogued as COSV66797200; called by muse, mutect2, varscan2
- SF3B2 | c.184G>T p.G62C | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV59428851; called by muse, mutect2, varscan2
- SFTPA2 | c.122T>A p.L41Q | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.247); catalogued as COSV64882648; called by muse, mutect2, varscan2
- SKA3 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 46/88 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV100006344, COSV53435469; called by muse, mutect2, varscan2
- SLC25A37 | c.212C>T p.T71I | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51564796; called by muse, mutect2, varscan2
- SLC49A4 | c.437+2T>C p.X146_splice | Splice Site (SNP) | VAF 24/49 reads (49%) | catalogued as COSV53747837; called by muse, mutect2, varscan2
- TAF5L | c.478G>T p.D160Y | Missense Mutation (SNP) | VAF 68/142 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV51082681; called by muse, mutect2, varscan2
- TARS2 | c.1847T>C p.V616A | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.083); catalogued as COSV60873758; called by muse, mutect2, varscan2
- TENM3 | c.6505C>T p.R2169C | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs267600105, COSV69312334, COSV69322897; called by muse, mutect2, varscan2
- THOC2 | c.3023C>T p.T1008I | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV55549414; called by muse, mutect2, varscan2
- THSD7A | c.2135C>T p.S712L | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV70267270; called by muse, mutect2, varscan2
- THSD7A | c.1267G>A p.A423T | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.071); catalogued as COSV70267276; called by muse, mutect2, varscan2
- TIAM1 | c.4198A>G p.R1400G | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV54559062; called by muse, mutect2, varscan2
- TIAM2 | c.901G>C p.E301Q | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.33); catalogued as COSV100020363, COSV59697022; called by muse, mutect2, varscan2
- TIE1 | c.1234G>C p.E412Q | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0.031); catalogued as COSV65250257; called by muse, mutect2, varscan2
- TKTL2 | c.1394C>G p.A465G | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.125); catalogued as COSV54918350, COSV54919736; called by muse, mutect2, varscan2
- TMEM164 | c.594C>A p.Y198* (on ENST00000372068 / NM_032227.4; = p.Y49* on NM_017698.2) | Nonsense Mutation (SNP) | VAF 111/404 reads (27%) | catalogued as COSV55813444; called by muse, mutect2, varscan2
- TMEM168 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 46/161 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57181334; called by muse, mutect2, varscan2
- TRO | c.1657G>C p.A553P | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV51503472; called by muse, mutect2, varscan2
- TSPAN8 | c.699G>T p.Q233H | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56078312, COSV56079123; called by muse, mutect2, varscan2
- UNC13C | c.3961G>T p.G1321* | Nonsense Mutation (SNP) | VAF 37/107 reads (35%) | catalogued as COSV52891397; called by muse, mutect2, varscan2
- USH2A | c.5224T>C p.F1742L | Missense Mutation (SNP) | VAF 51/180 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV56391733; called by muse, mutect2, varscan2
- USH2A | c.298C>T p.L100F | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1425614240, COSV56391747; called by muse, mutect2, varscan2
- USP11 | c.1974A>G p.E658= (on ENST00000218348; = p.E615= on NM_001371072.1) | Splice Region (SNP) | VAF 6/18 reads (33%) | catalogued as COSV54474287; called by muse, mutect2, varscan2
- ZMYND8 | c.1414A>G p.S472G (on ENST00000311275 / NM_001363741.2; = p.S492G on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.314); catalogued as COSV53691224; called by muse, mutect2, varscan2
- ZNF25 | c.454G>T p.G152W | Missense Mutation (SNP) | VAF 42/149 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56922421, COSV56923061; called by muse, mutect2, varscan2
- ZNF318 | c.6809A>G p.Q2270R | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as COSV58934101; called by muse, mutect2, varscan2
- ZNF382 | c.1052C>A p.P351H | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53089500; called by muse, mutect2, varscan2
- ZNF48 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs866318383, COSV60783610; called by muse, mutect2
- ZNF560 | c.1003C>T p.H335Y | Missense Mutation (SNP) | VAF 70/96 reads (73%) | SIFT tolerated (1); PolyPhen benign (0.216); catalogued as COSV56869178; called by muse, mutect2, varscan2
- ZNF610 | c.304A>G p.R102G | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.044); catalogued as rs756826256, COSV58345386; called by muse, mutect2, varscan2
- ZNF804B | c.178T>G p.C60G | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60835678; called by muse, mutect2, varscan2
- ZSWIM5 | c.2291G>A p.R764K | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62735175; called by muse, mutect2, varscan2
- ACSS2 | c.1845_1853del p.T616_C618del | In Frame Del (DEL) | VAF 15/84 reads (18%) | called by mutect2, pindel*, varscan2*
- COPB2 | c.1761_1777del p.L588Ifs*11 | Frame Shift Del (DEL) | VAF 12/58 reads (21%) | called by mutect2, pindel
- CRACD | c.1926del p.G643Afs*34 | Frame Shift Del (DEL) | VAF 13/22 reads (59%) | called by mutect2, pindel, varscan2
- FAM160A2 | c.458_460del p.E153del | In Frame Del (DEL) | VAF 14/50 reads (28%) | called by mutect2, pindel, varscan2
- FUT2 | c.1032dup | Frame Shift Ins (INS) | VAF 14/53 reads (26%) | called by mutect2, pindel, varscan2
- GPBP1 | c.257A>G p.H86R | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.242); called by mutect2, varscan2
- HERC2 | c.4189G>A p.D1397N | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- IGHV4-59 | c.145A>T p.S49C | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- IGKV1-9 | c.328T>A p.C110S | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- LTBP1 | c.4653_4655delinsTT p.C1552Ffs*16 (on ENST00000404816 / NM_206943.4; = p.C1226Ffs*16 on NM_000627.4) | Frame Shift Del (DEL) | VAF 20/86 reads (23%) | called by pindel, varscan2*
- MBL2 | c.327del p.S110Qfs*31 | Frame Shift Del (DEL) | VAF 21/93 reads (23%) | called by mutect2, pindel, varscan2
- MTMR1 | c.276_279dup p.Q94Gfs*15 | Frame Shift Ins (INS) | VAF 8/22 reads (36%) | called by mutect2, pindel, varscan2
- OR8B2 | c.794del p.G265Dfs*27 | Frame Shift Del (DEL) | VAF 17/54 reads (31%) | called by mutect2, pindel*
- POLQ | c.2271_2275del p.Y758Rfs*36 | Frame Shift Del (DEL) | VAF 18/59 reads (31%) | called by mutect2, pindel, varscan2
- PSG9 | c.1227G>T p.M409I | Missense Mutation (SNP) | VAF 63/324 reads (19%) | SIFT tolerated (0.81); PolyPhen benign (0.003); called by mutect2, varscan2
- PTEN | c.491dup p.V166Sfs*14 | Frame Shift Ins (INS) | VAF 21/41 reads (51%) | called by mutect2, pindel, varscan2
- SLC45A2 | c.1506del p.T503Pfs*6 | Frame Shift Del (DEL) | VAF 5/25 reads (20%) | called by mutect2, pindel, varscan2
- TNKS1BP1 | c.293_294del p.P98Lfs*8 | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | called by mutect2, pindel, varscan2
- TRAV8-7 | c.303T>A p.S101R | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- ADAM22 | c.153G>T p.V51= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV55981181; called by muse, mutect2, varscan2
- ADAMTS16 | c.180T>C p.Y60= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV56995236; called by mutect2, varscan2
- ADORA2A | c.825C>A p.V275= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as COSV58379503; called by muse, mutect2, varscan2
- ARHGEF1 | c.1002A>T p.P334= | Silent (SNP) | VAF 22/112 reads (20%) | catalogued as COSV61528413; called by muse, mutect2, varscan2
- BCHE | c.1560C>T p.V520= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as rs533603961, COSV52258544; called by muse, mutect2, varscan2
- C5AR2 | c.795C>A p.L265= | Silent (SNP) | VAF 28/150 reads (19%) | catalogued as COSV57256573; called by muse, mutect2, varscan2
- CAMTA1 | c.2355G>A p.G785= | Silent (SNP) | VAF 97/294 reads (33%) | catalogued as COSV57909500; called by muse, mutect2, varscan2
- CARD6 | c.966A>T p.P322= | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as COSV54566923, COSV54567166; called by muse, mutect2, varscan2
- CCDC113 | c.258G>T p.R86= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV54686625; called by muse, mutect2, varscan2
- CCR5 | c.135T>C p.F45= | Silent (SNP) | VAF 54/95 reads (57%) | catalogued as COSV52752081; called by muse, mutect2, varscan2
- CCR6 | c.1077G>A p.Q359= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV59474029; called by muse, mutect2, varscan2
- CDH10 | c.1608A>T p.T536= | Silent (SNP) | VAF 95/201 reads (47%) | catalogued as rs1242546002, COSV52586187; called by muse, mutect2, varscan2
- CHRM2 | c.909G>A p.Q303= | Silent (SNP) | VAF 24/63 reads (38%) | catalogued as COSV57776298; called by muse, mutect2, varscan2
- CRISP2 | c.30T>A p.V10= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as rs1355611169, COSV59255382; called by muse, mutect2, varscan2
- CYP26B1 | c.1092G>T p.L364= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV50011001, COSV50012722; called by muse, mutect2, varscan2
- DCHS1 | c.1014G>T p.G338= | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as COSV55038190; called by muse, mutect2, varscan2
- DIAPH2 | c.1531C>A p.R511= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs1409571572, COSV61259810, COSV61276815; called by muse, mutect2, varscan2
- FAM110B | c.51C>A p.P17= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as rs764284524, COSV64066264; called by muse, mutect2, varscan2
- FLCN | c.180G>T p.A60= | Silent (SNP) | VAF 29/44 reads (66%) | catalogued as COSV53260823; called by muse, mutect2, varscan2
- FMN2 | c.603G>A p.Q201= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV60437335; called by muse, mutect2
- FNDC1 | c.5160A>G p.L1720= | Silent (SNP) | VAF 48/120 reads (40%) | catalogued as COSV51941503; called by muse, mutect2, varscan2
- GCC2 | c.1383T>C p.G461= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as rs920490239, COSV59177717; called by muse, mutect2, varscan2
- GPR55 | c.489G>T p.V163= | Silent (SNP) | VAF 27/91 reads (30%) | catalogued as COSV67408051; called by muse, mutect2, varscan2
- GRM6 | c.2256C>T p.I752= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as rs376987111, COSV51447241; called by muse, varscan2
- IL20RA | c.858A>G p.A286= | Silent (SNP) | VAF 49/156 reads (31%) | catalogued as COSV57358982; called by muse, mutect2, varscan2
- KCNC4 | c.600C>A p.A200= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as rs1480632717, COSV63925976; called by muse, mutect2, varscan2
- KIF13A | c.5130C>T p.S1710= | Silent (SNP) | VAF 21/50 reads (42%) | catalogued as COSV52456192; called by muse, mutect2, varscan2
- KIF17 | c.783C>G p.T261= | Silent (SNP) | VAF 36/92 reads (39%) | catalogued as COSV56119648; called by muse, mutect2, varscan2
- L1CAM | c.297C>A p.G99= | Silent (SNP) | VAF 28/66 reads (42%) | catalogued as COSV62828765; called by muse, mutect2, varscan2
- LAMA1 | c.636A>T p.S212= | Silent (SNP) | VAF 25/76 reads (33%) | catalogued as COSV67539438; called by muse, mutect2, varscan2
- LRP1B | c.6015A>T p.P2005= | Silent (SNP) | VAF 27/75 reads (36%) | catalogued as COSV67241465; called by muse, mutect2, varscan2
- LRP2 | c.11925C>T p.C3975= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as rs143815721; called by muse, mutect2, varscan2
- MON2 | c.3792A>T p.L1264= | Silent (SNP) | VAF 34/83 reads (41%) | catalogued as COSV54809669; called by muse, mutect2, varscan2
- NHS | c.4791C>G p.R1597= | Silent (SNP) | VAF 34/93 reads (37%) | catalogued as COSV66277767; called by muse, mutect2, varscan2
- NID2 | c.396G>A p.V132= | Silent (SNP) | VAF 25/61 reads (41%) | catalogued as COSV53498799; called by muse, mutect2, varscan2
- OR5H14 | c.423C>T p.C141= | Silent (SNP) | VAF 50/244 reads (20%) | catalogued as rs763099291, COSV71194148; called by muse, varscan2
- PARPBP | c.849G>T p.V283= | Silent (SNP) | VAF 29/78 reads (37%) | catalogued as COSV59674659; called by muse, mutect2, varscan2
- PKD1L2 | c.2043G>T p.L681= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as rs1367157445, COSV55164468; called by muse, mutect2, varscan2
- PPA1 | c.372A>G p.E124= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV64684067; called by muse, mutect2, varscan2
- PPP4R1 | c.1104A>G p.S368= (on ENST00000400556 / NM_001042388.3; = p.S351= on NM_005134.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/89 reads (40%) | catalogued as COSV53282662; called by muse, mutect2, varscan2
- PRDX1 | c.282A>G p.Q94= | Silent (SNP) | VAF 62/179 reads (35%) | catalogued as COSV53114065; called by muse, mutect2, varscan2
- RGS7 | c.210A>G p.L70= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV58547543; called by muse, mutect2, varscan2
- RYR1 | c.3390C>A p.R1130= | Silent (SNP) | VAF 39/65 reads (60%) | catalogued as COSV62101694; called by muse, mutect2, varscan2
- TNMD | c.894C>G p.V298= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV65977361; called by muse, mutect2, varscan2
- TRIM43 | c.264T>G p.S88= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as COSV99719882; called by muse, mutect2, varscan2
- TRIP11 | c.2796T>A p.S932= | Silent (SNP) | VAF 45/129 reads (35%) | catalogued as COSV50932356; called by muse, mutect2, varscan2
- TRPC7 | c.321G>T p.G107= | Silent (SNP) | VAF 19/35 reads (54%) | catalogued as COSV61459829; called by muse, mutect2, varscan2
- TTBK1 | c.1554G>A p.V518= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV52493213; called by muse, mutect2, varscan2
- XDH | c.2751G>T p.G917= | Silent (SNP) | VAF 49/162 reads (30%) | catalogued as rs369230654, COSV65149693; called by muse, mutect2, varscan2
- ZFYVE28 | c.1338G>T p.G446= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as COSV52113357; called by muse, mutect2, varscan2
- ZMYND8 | c.2646C>A p.S882= (on ENST00000311275 / NM_001363741.2; = p.S856= on NM_012408.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as COSV53691205; called by muse, mutect2, varscan2
- ZNF91 | c.3054A>G p.G1018= | Silent (SNP) | VAF 30/52 reads (58%) | catalogued as COSV56086940; called by muse, mutect2, varscan2
- ERCC6 | c.1397+7668A>T | Intron (SNP) | VAF 17/52 reads (33%) | catalogued as COSV63391648; called by muse, mutect2, varscan2
- FABP5P3 | chr7:152446338 G>A | 3'Flank (SNP) | VAF 61/148 reads (41%) | catalogued as rs778599945; called by muse, mutect2, varscan2
- FAM153CP | chr5:178055896 G>A | 3'Flank (SNP) | VAF 25/43 reads (58%) | catalogued as rs1372179030; called by muse, mutect2, varscan2
- NACA | c.71-3959G>T | Intron (SNP) | VAF 11/39 reads (28%) | called by muse, mutect2, varscan2
- NDUFV3 | c.170-5539G>A | Intron (SNP) | VAF 45/134 reads (34%) | catalogued as rs200386429, COSV61087450; called by muse, mutect2, varscan2
- OAS1 | c.*21_*34delinsTT | 3'UTR (DEL) | VAF 11/33 reads (33%) | called by pindel, varscan2*
- PSG1 | c.1243+13del | Intron (DEL) | VAF 48/390 reads (12%) | called by mutect2, pindel, varscan2
